Surgical pathology report (de-identified scan), TCGA case TCGA-LN-A49K, project TCGA-ESCA (Esophageal Carcinoma), tissue source site ILSBIO, specimen TCGA-LN-A49K-01A (Primary Tumor).

[page 1 of 5]
ICA-0-3

Clinical Case Report

Carcinoma, squamous cell (For Collection of Cancerous Tissue)

8070/3

Site: esophagus, middle third C15.4

pw
10/2/12

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
	1 m 60	☐ Single ☒ Married	VIETNAMESE	
Gender	Weight	☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
☒ Male ☐ Female	57 kg		121/8	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Difficult to swallow especially when eating hard food.
Symptoms: Weight Loss
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☐ Post-menopausal	Date of First Menses	# of Pregnancies
	Date of Last Menses	# of Live Births
	Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____	
		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy ✓	A tumor was found in the esophagus	
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	Date of Diagnosis
T3 N0 M0 Stage: II A	

Treatment Information

SURGICAL TREATMENT		
Procedure	Date of Procedure	
Upper part of the esophagus was removed		
Primary Tumor		
Organ	Detailed Location	Size
Esophagus tumor	middle	3 x 2 x 2 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T3 N0 M0 Stage: II		

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)					
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)	
				/ / To	/ /
				/ / To	/ /
				/ / To	/ /
				/ / To	/ /
				/ / To	/ /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _

Preserved by: _

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
14 min		12 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
esophageal Tumor	3 x 2 x 2 cm	middle	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 3 N 0 M 0		Stage: II	
Notes:			

[page 5 of 5]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION				STRUCTURAL PATTERN			
	+	-			+	-	
Diffuse				Streaming			
Mosaic				Storiform			
Necrosis				Fibrosis			
Lymphocytic Infiltration				Palisading			
Vascular Invasion				Cystic Degeneration			
Clusterized				Bleeding			
Alveolar Formation				Myxoid Change			
Indian File				Psammona/Calcification			

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell			Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		

Otherwise Specified:

D1 78% D2 70% D3 78% D4 58%

recurrent 20%

2. Cellular Differentiation:

Well	Moderately	Poor

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis				
Hyperchromatism				
Nucleolar Prominent				
Multinucleated Giant Cell				
Mitotic Activity				
Nuclear Grade				

Histological Diagnosis: *Squamous Cell Carcinoma, G2*

Comments: _____

Date _____

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RESEARCH USE ONLY).

Reviewed (Initials)	Date Reviewed:	

8/30/12

Source: NCI Genomic Data Commons file bf2081d5-d157-4629-b7c0-1877405e679b (TCGA-LN-A49K.444D06CD-4B38-46C3-9773-815CB994DDB8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).